Somatic mutation profile of tumor specimen TCGA-85-A5B5-01A (aliquot TCGA-85-A5B5-01A-21D-A26M-08) from TCGA case TCGA-85-A5B5, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.7 years (21,450 days).
Specimen TCGA-85-A5B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5f8ea19-99c2-403d-b0bd-a0c2b5863795.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A5B5-10A (Blood Derived Normal), aliquot TCGA-85-A5B5-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe56e346-4b8a-4e53-9984-b9227d747d17

The open-access MAF lists 426 somatic variants for this specimen: 325 protein-altering or splice-affecting, 95 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 95, Nonsense Mutation 29, Frame Shift Del 9, Splice Region 3, 3'UTR 2, Frame Shift Ins 2, Intron 2, Splice Site 1, 5'Flank 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 42/48 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.1309G>T p.G437* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99907904; called by muse, mutect2, varscan2
- AACS | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs761419269, COSV99907906; called by muse, mutect2, varscan2
- ABI3BP | c.2437G>T p.V813F | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99426135; called by muse, mutect2, varscan2
- AC024598.1 | c.1012G>T p.G338W | Missense Mutation (SNP) | VAF 90/129 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV101237855; called by muse, mutect2, varscan2
- ACIN1 | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99399403; called by muse, mutect2, varscan2
- ADAMTS18 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99271966; called by muse, mutect2, varscan2
- ADAMTS20 | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV101166183; called by muse, mutect2, varscan2
- ADAMTS7 | c.3736G>T p.V1246F | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101183073; called by muse, mutect2, varscan2
- ADAT1 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100329180; called by muse, mutect2, varscan2
- ADD3 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99523310; called by muse, mutect2, varscan2
- AFF3 | c.2683G>T p.D895Y | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757874688, COSV100418513; called by muse, mutect2, varscan2
- AHRR | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100326982; called by muse, mutect2, varscan2
- ALKBH4 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1210298433, COSV99479255; called by muse, mutect2, varscan2
- ANK3 | c.5749G>T p.A1917S | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as COSV99779346; called by muse, mutect2, varscan2
- ANKRD11 | c.7442A>G p.K2481R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99968928; called by muse, mutect2, varscan2
- ANKRD30A | c.2844G>A p.M948I (on ENST00000611781; = p.M892I on NM_052997.2) | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64605965, COSV64619278; called by muse, mutect2, varscan2
- APOBEC3C | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.709); catalogued as rs201591623, COSV63865099, COSV63865382; called by muse, mutect2, varscan2
- ARHGAP30 | c.1333C>A p.R445S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100920115, COSV100920193; called by muse, mutect2, varscan2
- ATP1A4 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 103/194 reads (53%) | catalogued as COSV63623873; called by muse, mutect2, varscan2
- ATP8A1 | c.1341-1G>A p.X447_splice | Splice Site (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100045674; called by muse, mutect2, varscan2
- ATP8A2 | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99681233; called by muse, mutect2, varscan2
- ATP8B4 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 23/28 reads (82%) | catalogued as COSV99464705; called by muse, mutect2, varscan2
- BANP | c.338G>T p.C113F (on ENST00000286122; = p.C121F on NM_017869.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99621284; called by muse, mutect2, varscan2
- BCL2L15 | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100851575; called by muse, mutect2, varscan2
- BNIP5 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV101465135; called by muse, mutect2, varscan2
- BRINP2 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100837768; called by muse, mutect2, varscan2
- BRWD1 | c.771G>T p.L257F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100313191; called by muse, mutect2, varscan2
- BTBD8 | c.1049G>C p.W350S | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100730210; called by muse, mutect2, varscan2
- C19orf57 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100694671; called by muse, mutect2, varscan2
- C20orf96 | c.752G>T p.R251L (on ENST00000360321 / NM_153269.3; = p.R250L on NM_080571.1) | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as rs550866771, COSV100826689; called by muse, mutect2, varscan2
- C2CD2L | c.1570G>T p.V524L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV100371153, COSV60884010; called by muse, mutect2, varscan2
- C2CD6 | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99632503; called by muse, mutect2, varscan2
- C3 | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV99836443; called by muse, mutect2, varscan2
- CACNA2D1 | c.3302G>T p.R1101L (on ENST00000356253 / NM_001366867.1; = p.R1089L on NM_000722.4) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs143631985, COSV100665755, COSV100666394; called by muse, mutect2, varscan2
- CASR | c.2014T>A p.S672T (on ENST00000490131; = p.S749T on NM_000388.4) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99948768; called by muse, mutect2, varscan2
- CCDC158 | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs776672697, COSV101187202; called by muse, mutect2, varscan2
- CCDC191 | c.2464G>C p.V822L | Missense Mutation (SNP) | VAF 81/84 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99878098; called by muse, mutect2, varscan2
- CCDC66 | c.1382G>T p.R461L (on ENST00000394672 / NM_001353147.1; = p.R427L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745348880, COSV100413852; called by muse, mutect2, varscan2
- CCT8L2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100742655, COSV100743098; called by muse, mutect2, varscan2
- CD1D | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 50/255 reads (20%) | catalogued as COSV100939577; called by muse, mutect2, varscan2
- CD1E | c.257G>C p.S86T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV100936964; called by muse, mutect2, varscan2
- CD1E | c.920T>A p.F307Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV100936965; called by muse, mutect2, varscan2
- CDH8 | c.1694A>T p.N565I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV54847992; called by muse, mutect2, varscan2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 123/154 reads (80%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2, varscan2
- CDR1 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.135); catalogued as COSV100983393; called by muse, mutect2, varscan2
- CEP162 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100002621; called by muse, mutect2, varscan2
- CEP250 | c.3598A>T p.R1200W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100698863; called by muse, mutect2, varscan2
- CERKL | c.944T>C p.V315A (on ENST00000339098 / NM_001030311.2; = p.V289A on NM_201548.5) | Missense Mutation (SNP) | VAF 99/173 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as COSV100183469; called by muse, mutect2, varscan2
- CERKL | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183475, COSV59204839; called by muse, mutect2, varscan2
- CFAP100 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100729154, COSV61504760; called by muse, mutect2, varscan2
- CFTR | c.2486T>G p.L829* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99135147; called by muse, mutect2, varscan2
- CHN1 | c.863G>T p.C288F | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104402329, COSV99789087; called by muse, mutect2, varscan2
- CHST1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV100346161; called by muse, mutect2, varscan2
- CLCA1 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.364); catalogued as rs1385595269, COSV99322170; called by muse, mutect2, varscan2
- CLDN4 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV99936406; called by muse, mutect2, varscan2
- COL11A1 | c.1372C>A p.L458I | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV100615914; called by muse, mutect2, varscan2
- COL22A1 | c.4636G>T p.D1546Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100277579; called by muse, mutect2, varscan2
- COL4A2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100847301; called by muse, mutect2, varscan2
- COL6A6 | c.2446A>T p.S816C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV100650140; called by muse, mutect2, varscan2
- CYLC2 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100872412; called by muse, mutect2
- CYP26A1 | c.1327G>T p.V443L | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.96); PolyPhen benign (0.011); catalogued as COSV99814643; called by muse, mutect2, varscan2
- DCAF4 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV100610983; called by muse, mutect2, varscan2
- DCDC1 | c.2869C>A p.P957T (on ENST00000597505 / NM_001367979.1; = p.P64T on NM_020869.3) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100338054; called by muse, mutect2, varscan2
- DCSTAMP | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99886386; called by muse, mutect2, varscan2
- DDR2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906420; called by muse, mutect2, varscan2
- DEAF1 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100101952; called by muse, mutect2, varscan2
- DENND4B | c.238A>T p.S80C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100338962; called by muse, mutect2, varscan2
- DEPDC1 | c.1864C>T p.R622C (on ENST00000456315 / NM_001114120.3; = p.R338C on NM_017779.6) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as rs200248484, COSV63957627; called by muse, mutect2, varscan2
- DHX36 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100273500; called by muse, mutect2, varscan2
- DIPK2B | c.1248T>A p.C416* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as COSV101211655; called by muse, mutect2, varscan2
- DLGAP1 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.332); catalogued as COSV100229372, COSV59847195; called by muse, mutect2, varscan2
- DMD | c.3799T>C p.C1267R | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100819079; called by muse, mutect2, varscan2
- DMD | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs367774853, COSV99921211; called by muse, mutect2, varscan2
- DMGDH | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1166365473, COSV54862284, COSV99668735; called by muse, mutect2, varscan2
- DNAH5 | c.9617G>T p.G3206V | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209483, COSV99447926; called by muse, mutect2, varscan2
- DNAH7 | c.3496T>A p.Y1166N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100414644; called by muse, mutect2, varscan2
- DNAH8 | c.11425C>A p.L3809M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544299; called by muse, mutect2, varscan2
- DNAI4 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100925210; called by muse, varscan2
- DPY19L2 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100116399, COSV100116653; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 22/33 reads (67%) | catalogued as COSV58330771; called by mutect2, pindel, varscan2
- DRC7 | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395488; called by muse, mutect2, varscan2
- DRC7 | c.2621C>A p.A874D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV100395490; called by muse, mutect2, varscan2
- DSCAML1 | c.4075G>T p.V1359L (on ENST00000321322; = p.V1299L on NM_020693.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV100355520; called by muse, mutect2, varscan2
- DYNC1I1 | c.1005C>A p.Y335* | Nonsense Mutation (SNP) | VAF 56/182 reads (31%) | catalogued as COSV100268042, COSV61456877; called by muse, mutect2, varscan2
- EEF1A2 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53208516; called by muse, mutect2, varscan2
- EGFLAM | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV100380151; called by muse, mutect2, varscan2
- EIF2S3 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as COSV53406161, COSV99450793; called by muse, mutect2, varscan2
- EPHA6 | c.2200G>C p.G734R (on ENST00000389672 / NM_001080448.3; = p.G126R on NM_173655.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101061739; called by muse, mutect2, varscan2
- ESRRG | c.591G>T p.G197= | Splice Region (SNP) | VAF 34/86 reads (40%) | catalogued as rs777149329, COSV100752637; called by muse, mutect2, varscan2
- F9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/58 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99496484; called by muse, mutect2, varscan2
- FAM120A | c.2290C>G p.P764A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99465067; called by muse, mutect2, varscan2
- FASTKD5 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99417668; called by muse, mutect2, varscan2
- FBXL5 | c.995T>A p.V332E | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100377822; called by muse, mutect2, varscan2
- FHL5 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100459286, COSV58737580, COSV58738721; called by muse, mutect2, varscan2
- FLG | c.7513C>A p.H2505N | Missense Mutation (SNP) | VAF 124/628 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV100911402; called by muse, mutect2, varscan2
- FN1 | c.736T>G p.W246G | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116787; called by muse, mutect2, varscan2
- FOXJ1 | c.663C>A p.H221Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); catalogued as COSV99486861; called by muse, mutect2
- FRAS1 | c.8359A>T p.T2787S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99350379; called by muse, mutect2, varscan2
- FRY | c.5290A>G p.S1764G | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV100969039; called by muse, mutect2, varscan2
- FRY | c.8567G>T p.S2856I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as COSV100969040; called by muse, mutect2, varscan2
- GABBR2 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99409709; called by muse, mutect2, varscan2
- GABRA2 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100734086; called by muse, mutect2, varscan2
- GABRA4 | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973847; called by muse, mutect2, varscan2
- GABRR2 | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101298906; called by muse, mutect2
- GAD2 | c.1424T>C p.L475S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99393000; called by muse, mutect2, varscan2
- GALNT13 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101222532; called by muse, mutect2, varscan2
- GALNTL6 | c.972T>G p.F324L | Missense Mutation (SNP) | VAF 109/172 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101560205; called by muse, mutect2, varscan2
- GDF6 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99747893; called by muse, mutect2, varscan2
- GLI1 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99953961; called by muse, mutect2, varscan2
- GLYATL1 | c.257A>T p.E86V (on ENST00000317391 / NM_001354699.1; = p.E117V on NM_080661.4) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100265249; called by muse, mutect2, varscan2
- GPANK1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100788994; called by muse, mutect2, varscan2
- GPC2 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99444509; called by muse, mutect2, varscan2
- GPR158 | c.2826C>G p.N942K | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV100893206; called by muse, mutect2, varscan2
- GPRC6A | c.278T>A p.V93D | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs934086322, COSV100114241; called by muse, mutect2, varscan2
- GPRIN3 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100310679; called by muse, mutect2, varscan2
- GREB1 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 196/292 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as rs1024911228, COSV99302691; called by muse, mutect2, varscan2
- HBE1 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99496122; called by muse, mutect2, varscan2
- HCN1 | c.2366C>A p.S789* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100298492, COSV100299654, COSV57536392; called by muse, mutect2, varscan2
- HHIP | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV99666993; called by muse, mutect2, varscan2
- HHIPL2 | c.2106C>G p.S702R | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV58563853; called by muse, mutect2, varscan2
- HOXD4 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1278264422, COSV100106775; called by muse, mutect2, varscan2
- HPS3 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56053542, COSV99937324; called by muse, mutect2, varscan2
- IL27 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100112419; called by muse, mutect2, varscan2
- INPP4B | c.2494C>A p.R832S | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53711774, COSV53727337; called by muse, mutect2, varscan2
- INPP5B | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.283); catalogued as COSV100886141; called by muse, mutect2, varscan2
- ITGB4 | c.5437A>T p.T1813S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99563815; called by muse, mutect2, varscan2
- ITIH5 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV99904304; called by muse, mutect2, varscan2
- ITK | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 98/125 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV101439682; called by muse, mutect2, varscan2
- ITPRID1 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.442); catalogued as rs536235913, COSV60084176; called by muse, mutect2, varscan2
- JARID2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100521668, COSV59188307; called by muse, mutect2, varscan2
- JHY | c.2054A>T p.K685M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99913019; called by muse, mutect2, varscan2
- KCNA4 | c.983C>G p.T328S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV100068802; called by muse, mutect2, varscan2
- KCNC1 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789060; called by muse, mutect2, varscan2
- KCNF1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54462259, COSV99705660; called by muse, mutect2, varscan2
- KCNS2 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99751011; called by muse, mutect2, varscan2
- KCNS3 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV100411136; called by muse, mutect2, varscan2
- KIF21B | c.2471G>T p.R824L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100144277, COSV59759602; called by muse, mutect2
- KIR2DL1 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 116/978 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52406022; called by muse, mutect2
- KLHL1 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1233387340, COSV100917136, COSV64767845; called by muse, mutect2, varscan2
- KNG1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99405383; called by muse, mutect2
- KRT4 | c.1477G>C p.G493R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (1); catalogued as COSV99542812; called by muse, mutect2, varscan2
- KRT72 | c.1061G>C p.R354P | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs576034572, COSV99537163; called by muse, mutect2, varscan2
- KRT82 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.073); catalogued as COSV99233492; called by muse, mutect2, varscan2
- LAMA1 | c.7027C>G p.L2343V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV101055841; called by muse, mutect2, varscan2
- LAMA1 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101055844; called by muse, mutect2, varscan2
- LAMA4 | c.4375C>G p.L1459V (on ENST00000230538 / NM_001105206.3; = p.L1452V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100038077; called by muse, mutect2, varscan2
- LATS1 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99485674; called by muse, mutect2, varscan2
- LGSN | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101040431; called by muse, mutect2, varscan2
- LRP5 | c.1274G>T p.W425L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99591744; called by muse, mutect2, varscan2
- LRRK2 | c.2767C>G p.Q923E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV54144134; called by muse, mutect2, varscan2
- LRRTM1 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as COSV99702204; called by muse, mutect2, varscan2
- LYST | c.291C>G p.N97K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.075); catalogued as COSV101088928, COSV67706996; called by muse, mutect2, varscan2
- MACF1 | c.4813G>T p.A1605S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV99243164; called by muse, mutect2, varscan2
- MAGEB2 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as COSV66780120; called by muse, mutect2, varscan2
- MAGEE2 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.61); catalogued as COSV100973043; called by muse, mutect2, varscan2
- MAP2 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1477218364, COSV99559120; called by muse, mutect2, varscan2
- MAP2K5 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51609436, COSV99460171; called by muse, mutect2, varscan2
- MDGA1 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201721134, COSV99776677; called by muse, mutect2, varscan2
- ME3 | c.1101G>T p.W367C | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100660908; called by muse, mutect2, varscan2
- MEOX2 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1374143466, COSV100012096, COSV56294472; called by muse, mutect2
- MGAT4C | c.1415G>C p.S472T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100152821; called by muse, mutect2, varscan2
- MLXIPL | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100515272; called by muse, mutect2
- MMP2 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280326720, COSV99527641; called by muse, mutect2, varscan2
- MTMR6 | c.1843G>C p.G615R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101110751; called by muse, mutect2, varscan2
- MUC5B | c.13127C>G p.T4376S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.078); catalogued as rs943228511, COSV71594879; called by muse, mutect2, varscan2
- MYLK | c.2524G>A p.G842S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs1461689312, COSV100658833; called by muse, mutect2, varscan2
- MZF1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV99285144; called by muse, mutect2, varscan2
- NAALAD2 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100428293; called by muse, mutect2, varscan2
- NEB | c.7927G>T p.A2643S | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99419453; called by muse, mutect2, varscan2
- NEFM | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV99647147; called by muse, mutect2, varscan2
- NLRP12 | c.1800G>T p.Q600H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as COSV100145104; called by muse, mutect2, varscan2
- NLRP5 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as rs780240938, COSV66767831; called by muse, mutect2
- NOMO1 | c.3469G>A p.A1157T | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs775588268, COSV99814377; called by muse, mutect2
- NPAP1 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.517); catalogued as COSV100275095, COSV61511455; called by muse, mutect2, varscan2
- NRXN3 | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV73586282; called by muse, mutect2, varscan2
- NUP210L | c.2850G>A p.E950= | Splice Region (SNP) | VAF 19/164 reads (12%) | catalogued as COSV99667689; called by muse, mutect2, varscan2
- OLFM4 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs1274233970, COSV99524269; called by muse, mutect2, varscan2
- OPN5 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99789793; called by muse, mutect2, varscan2
- OR10G9 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100901551; called by muse, mutect2, varscan2
- OR10Q1 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.274); catalogued as rs749944005, COSV100372220; called by muse, mutect2, varscan2
- OR11H1 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99421724; called by muse, mutect2, varscan2
- OR11H12 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 32/328 reads (10%) | catalogued as COSV101612477; called by muse, mutect2, varscan2
- OR14K1 | c.376T>A p.C126S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99315081; called by muse, mutect2, varscan2
- OR2A4 | c.716C>G p.T239S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100199651; called by muse, mutect2, varscan2
- OR2D3 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV100505044; called by muse, mutect2, varscan2
- OR2G2 | c.661T>A p.S221T | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100189690; called by muse, mutect2, varscan2
- OR2T1 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs148087315; called by muse, mutect2, varscan2
- OR2T11 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100424759, COSV100424886; called by muse, mutect2, varscan2
- OR2T11 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV100424761; called by muse, mutect2, varscan2
- OR4C15 | c.602C>G p.A201G (on ENST00000314644; = p.A147G on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100115561, COSV100116073, COSV58951716; called by muse, mutect2, varscan2
- OR4C15 | c.742T>A p.F248I (on ENST00000314644; = p.F194I on NM_001001920.2) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.187); catalogued as COSV100115432, COSV58956275; called by muse, mutect2
- OR51B5 | c.299A>T p.Y100F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.144); catalogued as COSV100332499; called by muse, mutect2, varscan2
- OR51Q1 | c.592A>T p.S198C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100332878; called by muse, mutect2, varscan2
- OR52A1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.168); catalogued as COSV100200462; called by muse, mutect2
- OR52J3 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.405); catalogued as COSV100984840; called by muse, mutect2, varscan2
- OR5W2 | c.597A>T p.L199F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100747580; called by muse, mutect2, varscan2
- OR7D4 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100432671; called by muse, mutect2, varscan2
- OR8H1 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100476998, COSV57295762; called by muse, mutect2, varscan2
- PANX3 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV52512213, COSV99421404; called by muse, mutect2, varscan2
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDH11X | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 12/16 reads (75%) | catalogued as COSV100010704; called by mutect2, varscan2
- PCDH11Y | c.2844G>T p.M948I (on ENST00000400457 / NM_032973.2; = p.M937I on NM_032971.3) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as COSV99291105; called by muse, mutect2, varscan2
- PCDH15 | c.4213C>A p.R1405S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218567; called by muse, mutect2, varscan2
- PCDH9 | c.3408G>C p.L1136F (on ENST00000377865 / NM_203487.3; = p.L1102F on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.498); catalogued as COSV100119607, COSV100120395; called by muse, mutect2, varscan2
- PCDHB15 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99178873; called by muse, mutect2, varscan2
- PCIF1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100976027, COSV65026336; called by muse, mutect2, varscan2
- PCLO | c.14970A>T p.K4990N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100430360; called by muse, mutect2, varscan2
- PDE3A | c.666G>T p.R222S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as COSV100762024; called by muse, mutect2, varscan2
- PDE4DIP | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782759855, COSV100518296; called by muse, mutect2
- PDS5A | c.3691A>G p.I1231V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1433797034, COSV100337279; called by muse, mutect2, varscan2
- PDS5B | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100220798; called by muse, mutect2
- PDZD2 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99224558; called by muse, mutect2, varscan2
- PEAR1 | c.250C>G p.H84D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99441105; called by muse, mutect2, varscan2
- PHF19 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100384299; called by muse, mutect2, varscan2
- PHLDB1 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs782319586, COSV100616437; called by muse, mutect2, varscan2
- PLA2G2F | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747196063, COSV100907903, COSV64279922; called by muse, mutect2, varscan2
- PLXNB2 | c.3554G>A p.G1185D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as COSV100833980; called by muse, mutect2
- PMPCB | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV99971204; called by muse, mutect2, varscan2
- PPEF2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99714388; called by muse, mutect2, varscan2
- PPP1R42 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 56/123 reads (46%) | catalogued as COSV100221144; called by muse, mutect2, varscan2
- PRDM13 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100980454; called by muse, mutect2, varscan2
- PRKCB | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100333242; called by muse, mutect2, varscan2
- PTPRB | c.5906T>C p.L1969P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99716801; called by muse, mutect2, varscan2
- PTPRN2 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101153294; called by muse, mutect2, varscan2
- PTPRR | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99316983; called by muse, mutect2, varscan2
- PYDC2 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV101573356, COSV72921447; called by muse, mutect2, varscan2
- RASGEF1A | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 83/129 reads (64%) | catalogued as COSV100988654; called by muse, mutect2, varscan2
- REG3A | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as rs775928429, COSV100532633; called by muse, varscan2
- RESF1 | c.1790C>A p.T597K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100440261; called by muse, mutect2, varscan2
- RFTN2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV104400204, COSV99695075, COSV99695456; called by muse, mutect2, varscan2
- RFX3 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56517819; called by muse, mutect2
- RGS7 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100466250; called by muse, mutect2, varscan2
- RIF1 | c.743A>C p.Y248S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99690383; called by muse, mutect2, varscan2
- RUBCNL | c.1141C>G p.R381G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100528968, COSV59794894; called by muse, mutect2
- RUFY2 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV99769205; called by muse, mutect2, varscan2
- SCN11A | c.2565C>A p.H855Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV100181281; called by muse, mutect2, varscan2
- SERPINA4 | c.258C>A p.Y86* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100097052, COSV100097100; called by muse, mutect2, varscan2
- SERPINF2 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV100131868; called by muse, mutect2, varscan2
- SFTPD | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100954507; called by muse, mutect2, varscan2
- SFTPD | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100954508; called by muse, mutect2, varscan2
- SI | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV100014931; called by muse, mutect2, varscan2
- SIGLEC1 | c.3784C>G p.R1262G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99163876, COSV99165408; called by muse, mutect2, varscan2
- SLC14A1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 97/155 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV100424960; called by muse, mutect2, varscan2
- SLC16A4 | c.20A>T p.K7M | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100872930; called by muse, mutect2, varscan2
- SLC24A2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 72/91 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV99646231; called by muse, mutect2, varscan2
- SLC25A25 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV100895284; called by muse, mutect2, varscan2
- SLC27A6 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as COSV52489230; called by muse, mutect2, varscan2
- SLC28A3 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100883211; called by muse, mutect2, varscan2
- SLC5A4 | c.1799A>G p.K600R | Missense Mutation (SNP) | VAF 104/146 reads (71%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV99831833; called by muse, mutect2, varscan2
- SLC8A1 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs952882765, COSV100245505; called by muse, mutect2, varscan2
- SLC8A1 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317243583, COSV100247582, COSV60473723; called by muse, mutect2, varscan2
- SLITRK4 | c.2447C>A p.A816E | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100567261; called by muse, mutect2, varscan2
- SMTN | c.1294G>C p.G432R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100294219, COSV60778664; called by muse, mutect2, varscan2
- SNED1 | c.3808G>T p.V1270L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100122506, COSV60026807; called by muse, mutect2, varscan2
- SNTG1 | c.1231G>T p.G411* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | catalogued as COSV52468537; called by muse, mutect2, varscan2
- SNTN | c.94A>T p.R32W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV100662625; called by muse, mutect2, varscan2
- SNX20 | c.57C>A p.C19* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV56057008; called by mutect2, varscan2
- SPATA31D1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 91/101 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs780352940, COSV100782665, COSV61193952; called by muse, mutect2, varscan2
- SSTR4 | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99658512; called by muse, mutect2, varscan2
- STAU2 | c.136C>T p.L46F (on ENST00000524300 / NM_001164380.2; = p.L14F on NM_014393.2) | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100708757; called by muse, mutect2, varscan2
- STK3 | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69221781; called by muse, mutect2, varscan2
- STK31 | c.1871C>A p.P624H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100669283; called by muse, mutect2, varscan2
- SUSD5 | c.1752C>A p.C584* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100535043; called by muse, mutect2, varscan2
- SYN3 | c.119T>C p.M40T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs765668968, COSV100248802; called by muse, mutect2, varscan2
- SYNE1 | c.162T>G p.F54L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99559360; called by muse, mutect2, varscan2
- SYT14 | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99654960; called by muse, mutect2, varscan2
- SYT4 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99673591; called by muse, mutect2, varscan2
- TAAR6 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99256586; called by muse, mutect2, varscan2
- TAF6 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100612667, COSV59843585; called by muse, mutect2, varscan2
- TERF2 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99651409; called by muse, mutect2, varscan2
- TEX47 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99787171, COSV99787234; called by muse, mutect2, varscan2
- TFE3 | c.1211A>T p.Q404L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100252470; called by muse, mutect2, varscan2
- TG | c.3719C>T p.S1240F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV99600118; called by muse, mutect2, varscan2
- TIGIT | c.667C>A p.H223N | Missense Mutation (SNP) | VAF 126/447 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV101048012; called by muse, varscan2
- TIGIT | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 157/490 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV101048015; called by muse, varscan2
- TLN2 | c.4719C>A p.N1573K | Missense Mutation (SNP) | VAF 98/123 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV100168649; called by muse, mutect2, varscan2
- TMEM179 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.401); catalogued as COSV100482019; called by muse, mutect2, varscan2
- TOX2 | c.1420A>T p.S474C (on ENST00000358131 / NM_001098798.2; = p.S450C on NM_032883.3) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100363687; called by muse, mutect2, varscan2
- TPO | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.034); catalogued as COSV100220479; called by muse, mutect2, varscan2
- TRAM1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV99140747; called by muse, mutect2, varscan2
- TRAP1 | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV99893344; called by muse, mutect2, varscan2
- TRIM2 | c.1613G>C p.G538A (on ENST00000437508; = p.G565A on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/142 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100107782; called by muse, mutect2, varscan2
- TRIM4 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs191380095; called by muse, mutect2, varscan2
- TRIM54 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 170/261 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99940519; called by muse, mutect2, varscan2
- TRIP11 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV99970538; called by muse, mutect2, varscan2
- TSHZ2 | c.2173A>T p.T725S | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100295799; called by muse, mutect2, varscan2
- TSPYL5 | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.505); catalogued as COSV100438879; called by muse, mutect2, varscan2
- TTN | c.85985A>G p.N28662S (on ENST00000591111; = p.N21238S on NM_003319.4) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | PolyPhen probably damaging (0.994); catalogued as COSV100604469; called by muse, mutect2, varscan2
- TTN | c.56179C>A p.P18727T (on ENST00000591111; = p.P11303T on NM_003319.4) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | PolyPhen probably damaging (0.999); catalogued as COSV100604472; called by muse, mutect2, varscan2
- TTN | c.10937G>C p.G3646A (on ENST00000591111; = p.G3600A on NM_003319.4) | Missense Mutation (SNP) | VAF 50/176 reads (28%) | catalogued as COSV59903550; called by muse, mutect2, varscan2
- UNC13A | c.3281A>C p.D1094A | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99407781; called by muse, mutect2, varscan2
- WDR91 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.175); catalogued as COSV100615651; called by muse, mutect2, varscan2
- WFDC8 | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99250374; called by muse, mutect2
- XIRP2 | c.4013C>A p.T1338N (on ENST00000628543; = p.T1513N on NM_152381.6) | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs1205269410, COSV99741207; called by muse, mutect2, varscan2
- XRN2 | c.2607G>C p.W869C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101018199; called by muse, mutect2, varscan2
- ZBTB20 | c.1067G>T p.C356F (on ENST00000474710 / NM_001164342.2; = p.C283F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/124 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1560114426, COSV100613407; called by muse, mutect2, varscan2
- ZFP3 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100603721, COSV59583813; called by muse, mutect2, varscan2
- ZMYND15 | c.1763G>T p.R588L (on ENST00000433935 / NM_001136046.3; = p.R549L on NM_032265.2) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV99351184; called by muse, mutect2, varscan2
- ZNF208 | c.2180del p.G727Afs*15 | Frame Shift Del (DEL) | VAF 59/195 reads (30%) | catalogued as COSV68113064; called by mutect2, pindel, varscan2
- ZNF208 | c.775T>C p.C259R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101236973; called by muse, mutect2, varscan2
- ZNF35 | c.1100G>T p.C367F | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56076037, COSV99940017; called by muse, mutect2, varscan2
- ZNF382 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV99497685; called by muse, mutect2, varscan2
- ZNF551 | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99989892; called by muse, mutect2, varscan2
- ZNF551 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 110/174 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56591742, COSV99989896; called by muse, mutect2, varscan2
- ZNF572 | c.952C>T p.H318Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100073896; called by muse, mutect2, varscan2
- ZNF587 | c.1339A>T p.R447W | Missense Mutation (SNP) | VAF 134/176 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV100299390; called by muse, mutect2, varscan2
- ZNF614 | c.613del p.H205Mfs*46 | Frame Shift Del (DEL) | VAF 45/141 reads (32%) | catalogued as rs780714895; called by mutect2, pindel, varscan2
- AVPR1B | c.1165del p.L389Sfs*7 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- CILP | c.2195del p.G732Afs*25 | Frame Shift Del (DEL) | VAF 76/154 reads (49%) | called by pindel, varscan2
- DPYSL3 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.052); called by mutect2, varscan2
- FCGBP | c.10579G>T p.E3527* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- FOLH1 | c.449del p.G150Dfs*25 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- KIF21A | c.1662del p.K555Rfs*45 (on ENST00000361418 / NM_001378440.1; = p.K555Rfs*32 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- MMP28 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR5B3 | c.600dup p.V201Cfs*89 | Frame Shift Ins (INS) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- PKD1L2 | n.3290A>G | Splice Region (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- RAB3C | c.240del p.K80Nfs*29 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- RASGEF1C | c.503dup p.P170Afs*53 | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- SPDYE5 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNXB | c.9635del p.P3212Lfs*4 (on ENST00000647633; = p.P2965Lfs*4 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- TPTE | c.1649C>A p.S550Y (on ENST00000618007 / NM_199261.4; = p.S532Y on NM_199259.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TRAV8-6 | c.296C>A p.S99* | Nonsense Mutation (SNP) | VAF 84/149 reads (56%) | called by muse, mutect2, varscan2
- TRGV2 | c.250G>T p.G84W | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ADAMTS6 | c.1440A>C p.P480= | Silent (SNP) | VAF 78/100 reads (78%) | called by muse, mutect2, varscan2
- AFF3 | c.735T>A p.P245= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100418514; called by muse, mutect2, varscan2
- AMPD3 | c.312G>T p.P104= (on ENST00000396553 / NM_001025389.2; = p.P113= on NM_000480.3) | Silent (SNP) | VAF 59/141 reads (42%) | catalogued as COSV101158138, COSV67332758; called by muse, mutect2, varscan2
- ASXL3 | c.3381C>A p.T1127= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99324241; called by muse, mutect2, varscan2
- BAG4 | c.405G>T p.A135= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as COSV99781778; called by muse, mutect2, varscan2
- CDH23 | c.5493C>A p.L1831= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV99820154; called by muse, mutect2, varscan2
- CDH9 | c.1755T>A p.T585= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99142922; called by muse, mutect2, varscan2
- CGA | c.156C>T p.C52= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV63644158; called by muse, mutect2, varscan2
- CPA2 | c.495C>T p.T165= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs560132249, COSV99743930; called by muse, mutect2, varscan2
- CRYBA4 | c.309T>C p.R103= | Silent (SNP) | VAF 76/128 reads (59%) | catalogued as COSV100697783; called by muse, mutect2, varscan2
- CSMD2 | c.3186C>T p.T1062= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99588430; called by muse, mutect2, varscan2
- CXCL9 | c.27C>T p.L9= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV99345714; called by muse, mutect2, varscan2
- DCHS1 | c.2088C>A p.A696= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100201883; called by muse, mutect2, varscan2
- DDIT4L | c.375G>C p.V125= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99913868; called by muse, mutect2, varscan2
- DERA | c.549G>T p.G183= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV101397363; called by muse, mutect2, varscan2
- DNAAF6 | c.168T>A p.S56= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as COSV100314474; called by muse, mutect2, varscan2
- FAM133B | c.75T>A p.S25= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV101300206; called by muse, mutect2, varscan2
- FAM47C | c.2766C>T p.I922= | Silent (SNP) | VAF 69/83 reads (83%) | catalogued as rs868944554, COSV100792434; called by muse, mutect2, varscan2
- FAP | c.1896G>T p.L632= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV99502034; called by muse, mutect2, varscan2
- FBXO34 | c.759T>C p.S253= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV100571897; called by muse, mutect2, varscan2
- FBXW7 | c.663A>G p.Q221= (on ENST00000281708 / NM_001349798.2; = p.Q141= on NM_018315.5) | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs150895624; called by muse, mutect2, varscan2
- FGGY | c.1452C>G p.S484= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV58026973, COSV58046049; called by muse, mutect2, varscan2
- FLG | c.7512C>A p.S2504= | Silent (SNP) | VAF 123/632 reads (19%) | catalogued as COSV100911403, COSV64247092; called by muse, mutect2, varscan2
- FLG | c.1536T>A p.G512= | Silent (SNP) | VAF 271/609 reads (44%) | catalogued as COSV100911404; called by muse, mutect2, varscan2
- GDF3 | c.550C>T p.L184= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100325221; called by muse, mutect2, varscan2
- GPR78 | c.673C>A p.R225= | Silent (SNP) | VAF 43/55 reads (78%) | catalogued as rs778237308, COSV101223952; called by muse, mutect2, varscan2
- GRM4 | c.2547G>A p.P849= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs570055645, COSV100946031; called by muse, mutect2, varscan2
- GTF3C1 | c.3894G>T p.R1298= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100649227; called by muse, mutect2, varscan2
- H2AC20 | c.24A>T p.G8= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV100479783; called by muse, mutect2, varscan2
- H3C13 | c.75G>T p.A25= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100516071, COSV58943663; called by muse, mutect2, varscan2
- HCRTR2 | c.624G>A p.T208= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs201870257, COSV63796862; called by muse, mutect2, varscan2
- HGF | c.1597C>A p.R533= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV55952593, COSV99736413; called by muse, mutect2, varscan2
- HNRNPK | c.1260G>A p.S420= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs751986467, COSV61090273; called by muse, mutect2, varscan2
- HOXB4 | c.171C>G p.R57= | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as COSV100203713; called by muse, varscan2
- IMPG1 | c.1470C>T p.S490= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100886308, COSV64056938; called by muse, mutect2, varscan2
- INPP5D | c.1317G>A p.A439= (on ENST00000445964 / NM_001017915.3; = p.A438= on NM_005541.5) | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs531976699, COSV100856675; called by muse, mutect2
- IPO9 | c.2175G>T p.L725= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV100843381; called by muse, mutect2, varscan2
- KRT7 | c.258G>A p.R86= | Silent (SNP) | VAF 62/123 reads (50%) | catalogued as COSV100081452; called by muse, mutect2, varscan2
- KRTAP15-1 | c.270C>T p.N90= | Silent (SNP) | VAF 51/111 reads (46%) | catalogued as COSV100481617; called by muse, mutect2, varscan2
- LAMA1 | c.4551C>A p.V1517= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV67545975; called by muse, mutect2, varscan2
- LHX9 | c.663C>A p.T221= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs148334914, COSV100435768; called by muse, mutect2, varscan2
- LRRTM4 | c.591C>A p.S197= | Silent (SNP) | VAF 75/123 reads (61%) | catalogued as COSV101297501, COSV69139225; called by muse, mutect2, varscan2
- MAGEC2 | c.156C>T p.P52= | Silent (SNP) | VAF 65/76 reads (86%) | catalogued as COSV99909512; called by muse, mutect2, varscan2
- MAU2 | c.138G>A p.L46= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1340231119, COSV99448555; called by muse, mutect2, varscan2
- MEI1 | c.2358T>C p.F786= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100299804; called by muse, mutect2, varscan2
- MORC1 | c.1884A>T p.T628= | Silent (SNP) | VAF 137/150 reads (91%) | catalogued as COSV99225679; called by muse, mutect2, varscan2
- MUC16 | c.11151A>G p.T3717= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as rs771271657, COSV101199333; called by muse, mutect2, varscan2
- MUC17 | c.12246G>T p.T4082= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as rs201108444, COSV100072640; called by muse, mutect2, varscan2
- MUC5B | c.13128C>A p.T4376= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV101500222; called by muse, varscan2
- MYLK2 | c.396A>T p.A132= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV101044734; called by muse, mutect2, varscan2
- NAP1L3 | c.270C>G p.A90= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100220281; called by muse, mutect2, varscan2
- NCKAP1 | c.1704A>G p.A568= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV100720139; called by muse, mutect2, varscan2
- NELL2 | c.1539C>A p.G513= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV100419268; called by muse, mutect2, varscan2
- NEXMIF | c.1065G>A p.L355= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV50032237; called by muse, mutect2, varscan2
- NLRP2 | c.1728G>T p.R576= | Silent (SNP) | VAF 53/80 reads (66%) | catalogued as COSV99672141; called by muse, mutect2, varscan2
- NRXN3 | c.480C>G p.A160= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ODF3L2 | c.850C>T p.L284= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV52746222, COSV99198967; called by muse, mutect2, varscan2
- ONECUT1 | c.690G>T p.G230= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV100009129; called by muse, mutect2, varscan2
- OR11H12 | c.624A>C p.P208= | Silent (SNP) | VAF 14/94 reads (15%) | called by mutect2, varscan2
- OR11H6 | c.567C>A p.P189= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV100209766; called by muse, mutect2, varscan2
- OR4Q3 | c.441C>G p.P147= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV59177689; called by muse, mutect2
- PAPPA2 | c.1986C>A p.P662= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100866708, COSV100867070, COSV62774779; called by muse, mutect2, varscan2
- PCDH1 | c.384T>G p.P128= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99745907; called by muse, mutect2, varscan2
- PCDH8 | c.2286G>T p.L762= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100131432; called by muse, mutect2, varscan2
- PCDHB3 | c.735G>A p.P245= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs782429807, COSV50568772, COSV50622650; called by muse, mutect2, varscan2
- PDCD11 | c.3649T>C p.L1217= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100874283; called by muse, mutect2, varscan2
- PDE4D | c.168G>A p.L56= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV101550432; called by muse, mutect2, varscan2
- PKHD1L1 | c.4989G>T p.L1663= | Silent (SNP) | VAF 61/274 reads (22%) | catalogued as COSV101005919; called by muse, mutect2, varscan2
- PLA2G1B | c.342G>A p.E114= | Silent (SNP) | VAF 83/185 reads (45%) | catalogued as COSV100387515; called by muse, mutect2, varscan2
- PNMA8B | c.1134C>G p.V378= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100885383; called by muse, mutect2, varscan2
- PSG3 | c.300A>C p.T100= | Silent (SNP) | VAF 149/667 reads (22%) | catalogued as rs1195873294, COSV100548847; called by muse, mutect2, varscan2
- PXYLP1 | c.282C>T p.F94= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as COSV99649364; called by muse, mutect2, varscan2
- RGPD2 | c.4029G>A p.E1343= | Silent (SNP) | VAF 103/484 reads (21%) | catalogued as COSV100552928; called by muse, mutect2, varscan2
- ROBO2 | c.235C>A p.R79= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs768561235, COSV100165683; called by muse, mutect2, varscan2
- SCN10A | c.5670A>T p.P1890= | Silent (SNP) | VAF 59/73 reads (81%) | catalogued as COSV101479336; called by muse, mutect2, varscan2
- SERPINA11 | c.1257A>T p.P419= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100593999; called by muse, mutect2, varscan2
- SI | c.1128G>A p.R376= | Silent (SNP) | VAF 109/1115 reads (10%) | catalogued as COSV100014928; called by muse, mutect2
- SLC1A3 | c.486A>T p.V162= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99467351; called by muse, mutect2, varscan2
- SLC2A2 | c.132T>C p.H44= | Silent (SNP) | VAF 194/209 reads (93%) | catalogued as COSV100049224; called by muse, mutect2, varscan2
- SLC2A3 | c.588C>A p.I196= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV99306438; called by muse, mutect2, varscan2
- SMARCC2 | c.1263C>T p.T421= | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV99911117; called by muse, mutect2, varscan2
- SOX17 | c.63C>G p.P21= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV52025303, COSV99810472; called by muse, mutect2, varscan2
- SOX4 | c.54G>A p.E18= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs749349604, COSV99781973; called by muse, mutect2, varscan2
- SPATA31D1 | c.102G>T p.G34= | Silent (SNP) | VAF 90/100 reads (90%) | catalogued as COSV100782666; called by muse, mutect2, varscan2
- SPPL2B | c.1485G>T p.L495= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV101476105; called by muse, mutect2, varscan2
- SSU72P8 | c.252C>A p.I84= | Silent (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- SYNE2 | c.18294A>G p.A6098= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100647327; called by muse, mutect2, varscan2
- TRIM3 | c.1257G>C p.L419= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100624341; called by muse, mutect2, varscan2
- TRPM3 | c.1074C>G p.P358= (on ENST00000357533 / NM_001366142.2; = p.P203= on NM_020952.6) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100676506, COSV100677123; called by muse, mutect2, varscan2
- TRPM6 | c.3345C>A p.L1115= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1270391366, COSV100666123; called by muse, mutect2, varscan2
- ZDHHC5 | c.915C>T p.S305= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs749964183, COSV99762251; called by muse, mutect2, varscan2
- ZNF80 | c.243G>A p.E81= | Silent (SNP) | VAF 58/63 reads (92%) | catalogued as COSV100351987; called by muse, mutect2, varscan2
- ZNF804B | c.822C>T p.H274= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100302939; called by muse, mutect2, varscan2
- ZNF91 | c.3336C>A p.G1112= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV100322532; called by muse, mutect2, varscan2
- ZNHIT1 | c.423G>T p.L141= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs754430245, COSV100521986; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500936 C>A | 5'Flank (SNP) | VAF 12/35 reads (34%) | catalogued as rs1334871240; called by muse, mutect2, varscan2
- CCNF | c.17-122C>T | Intron (SNP) | VAF 41/247 reads (17%) | catalogued as COSV53542214; called by muse, mutect2, varscan2
- DENND10P1 | n.897G>A | RNA (SNP) | VAF 27/73 reads (37%) | catalogued as rs1028027555; called by muse, mutect2, varscan2
- POLR3G | c.*37A>C | 3'UTR (SNP) | VAF 27/32 reads (84%) | catalogued as COSV101209784; called by muse, mutect2, varscan2
- TBRG4 | c.908-98A>G | Intron (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99345342; called by muse, mutect2, varscan2
- ZNF99 | c.*218del | 3'UTR (DEL) | VAF 26/171 reads (15%) | catalogued as rs1268037272; called by pindel, varscan2
